CGCI case HTMCP-01-17-00570 — HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma (CGCI-HTMCP-DLBCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/fe7d6d75-3e11-47d3-9c87-b7bac6d64272

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 60 years; Vital status: Alive.

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: ICD-O-3 morphology code: 9680/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Lymph node, NOS; Classification of tumor: primary; Age at diagnosis: 60.6 years (22,130 days); Year of diagnosis: 2014; Method of diagnosis: Biopsy; Ann Arbor clinical stage: Stage III; Ann Arbor pathologic stage: Stage III; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,301 days (3.6 years); Max tumor bulk site: Inguinal.
   Pathology details: Lymph node involved site: Iliac, NOS; Lymph nodes positive: 2; Lymph nodes tested: 2; Tumor largest dimension diameter: 3.6 cm.
   Pathology details: Lymph node involved site: Inguinal.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis.

Follow-up (3 entries)
- Days to follow up: 0 days; Karnofsky performance status: 90; ECOG performance status: 0.
- Days to follow up: 1,301 days (3.6 years); Disease response: Tumor Free; Imaging type: PET; Imaging result: Negative.
- Follow-up contact recording only the day: day -8,975.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL2 (IHC): Positive.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- BCL6 translocation (FISH): Abnormal, NOS.
- CD10 (IHC): Negative; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD23 (IHC): Negative.
- CD3 (IHC): Negative.
- CD30 (IHC): Positive.
- CD79A (IHC): Positive.
- IRF4 (IHC): Positive; Specialized molecular test: MUM1 > 30%.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC gain (FISH): Abnormal, NOS.
- PAX5 (IHC): Positive.
- TP53 (IHC): Positive; Specialized molecular test: P53 > 20%.
- Lactate Dehydrogenase 322 [Blood test normal range upper: 246].
- Epstein-Barr Virus (ISH): Negative.

Other clinical attributes
- Day -8,975: Risk factors: HIV/AIDS.
- Day -8,975: Comorbidities: HIV/AIDS.
- Day 0: Cdc hiv risk factors: Homosexual Contact.
- Day 0: Weight: 93.5 kg; Height: 181 cm; BMI: 28.5; CD4 count: 146; Haart treatment indicator: Yes; HIV viral load: 18168.

Exposures
- Pack years smoked: 90.

Biospecimens (2 samples)
- Sample HTMCP-01-17-00570-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-01-17-00570-01Z: Sample type: Tumor; Tissue type: Tumor.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Diffuse large B-cell lymphoma (DLBCL) NOS (any anatomic site nodal or extranodal); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- History of disease: Year of HIV diagnosis: 1989; Haart therapy prior to diagnosis: Yes; Haart therapy at diagnosis: Yes; Cdc HIV risk group: Homosexual or bisexual contact.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: Iliac.
- Primary pathology, Tumor tissue sites: Submitted tumor site: No Known Extranodal Involvement.
- Primary pathology: Method initial path diagnosis: Biopsy (all types); Lymph nodes examined: Yes.
- Tests performed: LDH level: 322.
- Tests performed, Genetic testing results, Genetic testing result 1: Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunophenotypic analysis tested: BCL2; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: CD20; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunophenotypic analysis tested: CD23; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 7: Immunophenotypic analysis tested: PAX5; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 8: Immunophenotypic analysis tested: CD30; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 1: Genetic abnormality tested: C-myc; Genetic abnormality results: Gain.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 2: Genetic abnormality tested: BCL6.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-01-17-00570-01B-01E-14095:
- % tumour top: 90
- % tumour bottom: 90

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-01-17-00570-01B-01S-14095:
- % tumour top: 90
- % tumour bottom: 90
